FM case AD6357 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/994c4e48-1493-4aea-b734-f3d6b8b92bf8

Female, 59.3 years: Clear cell carcinoma (ICD-O-3 8310/3) of the ovary; metastasis biopsied or resected from the fallopian tube. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
